CCDI case PBCNZK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/e5a3a165-8b92-4fbf-98bf-32655de5911b

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.7 years (3,545 days).

Biospecimens (3 samples)
- Sample 0DWERS: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWES0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWES9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
